Gene-level copy-number profile of tumor specimen TCGA-DX-AB2Z-01A from TCGA case TCGA-DX-AB2Z, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-DX-AB2Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.50efa72d-44c3-4921-a289-9664df662f8e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/21c2fe57-0790-4e1e-933d-61d254ebe2d2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 106; copy number 1: 1,904; copy number 2: 19,068; copy number 3: 22,154; copy number 4: 10,671; copy number 5: 2,467; copy number 6: 1,786; copy number 7: 819; copy number 8: 509; copy number 9: 106; copy number 10: 81; copy number 11: 107; copy number 13: 29; copy number 14: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB2Z-01A-11D-A386-01): tumor purity 0.28, ploidy 3.08, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 106 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,782,993–22,509,406, 94 genes (broad region; genes not listed).
- chr15:47,525,169–47,527,756, 1 gene: AC009558.2.
- chr20:35,953,617–36,270,918, 11 genes: SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1, AL121895.2, AAR2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,652 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:168,249,522–168,830,599, 1 gene, copy number 8 (within-gene range 6–8): EGFEM1P.
- chr3:168,475,198–184,773,178, 295 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr3:191,641,135–194,071,025, 32 genes, copy number 7 (within-gene range 5–7): Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222, FGF12, FGF12-AS1, FGF12-AS2, FGF12-AS3, AC026671.1, RNU1-20P, MB21D2, AC092966.1, VEZF1P1, PLAAT1, ATP13A5, ATP13A5-AS1, ATP13A4, ATP13A4-AS1, AC048351.1, OPA1, OPA1-AS1, Y_RNA, RN7SL447P, AC069421.1, AC069421.2, AC069421.3, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028.
- chr3:196,027,183–196,943,543, 44 genes, copy number 10: TFRC, AC024937.1, RNU7-18P, LINC00885, ZDHHC19, Y_RNA, SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P, UBXN7, RNU6-1279P, RN7SL434P, RN7SL738P, AC083822.1, UBXN7-AS1, AC117490.1, RNF168, AC117490.2, SMCO1, AC092933.1, RPS29P3, WDR53, FBXO45, AC092933.2, LINC01063, NRROS, PIGX, CEP19, RNU6-646P, PAK2, RNU4-89P, RNU6-42P, SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2.
- chr4:12,223,445–21,948,772, 96 genes, copy number 7–13 (within-gene range 5–13) (broad region; genes not listed).
- chr5:37,939,365–40,053,324, 32 genes, copy number 8 (within-gene range 4–8): AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR, LIFR-AS1, MIR3650, AC010425.1, OSMR-AS1, AC091435.1, AC091435.2, OSMR, RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603.
- chr5:42,423,439–51,665,048, 82 genes, copy number 7–9 (broad region; genes not listed).
- chr7:159,231,435–159,233,377, 1 gene, copy number 10: PIP5K1P2.
- chr8:97,772,313–98,093,610, 12 genes, copy number 9 (within-gene range 6–9): Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5.
- chr9:3,181,342–11,013,096, 110 genes, copy number 7–8 (broad region; genes not listed).
- chr9:12,287,320–12,300,451, 2 genes, copy number 8: JKAMPP1, RNU2-47P.
- chr14:22,630,929–22,999,078, 23 genes, copy number 7 (within-gene range 2–7): OR6J1, AL160314.1, AL160314.2, OR6E1P, AL160314.3, AL135998.1, OXA1L, SLC7A7, MRPL52, MMP14, Y_RNA, Y_RNA, LRP10, REM2, RBM23, PRMT5-AS1, PRMT5, AL132780.1, HAUS4, AL132780.3, MIR4707, AJUBA, AL132780.2.
- chr14:28,318,141–42,808,112, 221 genes, copy number 7–13 (broad region; genes not listed).
- chr14:57,993,545–62,130,962, 86 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr14:65,410,592–65,744,121, 1 gene, copy number 7 (within-gene range 5–7): FUT8.
- chr14:65,528,830–68,869,951, 61 genes, copy number 7 (broad region; genes not listed).
- chr14:68,887,785–68,888,084, 1 gene, copy number 7: HMGN1P3.
- chr14:70,581,257–76,263,474, 160 genes, copy number 7 (broad region; genes not listed).
- chr17:61,679,139–64,020,634, 87 genes, copy number 7 (broad region; genes not listed).
- chr18:1,883,524–2,489,426, 1 gene, copy number 14 (within-gene range 6–14): AP005230.1.
- chr18:23,197,144–26,657,401, 65 genes, copy number 7–11 (within-gene range 2–11) (broad region; genes not listed).
- chr18:26,685,954–26,703,638, 3 genes, copy number 7: AC012588.1, PCAT18, U3.
- chr18:28,824,652–29,048,719, 2 genes, copy number 8: AC023932.1, RNU6-408P.
- chr18:38,655,209–39,800,322, 6 genes, copy number 9 (within-gene range 4–9): AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66.
- chr18:48,475,487–48,479,228, 3 genes, copy number 8: RNA5SP456, AC024288.1, POLR3GP2.
- chr18:48,564,795–48,568,342, 1 gene, copy number 8: AC048380.2.
- chr20:31,285,317–31,723,989, 28 genes, copy number 11: AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON.
- chr20:33,407,957–34,540,748, 36 genes, copy number 10 (within-gene range 3–10): SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2, ASIP, XPOTP1, AL035458.2, AL035458.1, AHCY, AL356299.2, AL356299.1, ITCH, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1.
- chr20:35,433,029–35,950,370, 27 genes, copy number 7 (within-gene range 0–7): GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P.
- chr22:18,833,694–21,081,018, 133 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
